Somatic mutation profile of tumor specimen TCGA-A2-A1G0-01A (aliquot TCGA-A2-A1G0-01A-11D-A13L-09) from TCGA case TCGA-A2-A1G0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.3 years (18,002 days).
Specimen TCGA-A2-A1G0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 786697d0-192f-4d40-9c85-a5b31b7b7a7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1G0-10A (Blood Derived Normal), aliquot TCGA-A2-A1G0-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d93c8f32-8a64-4bcc-84e0-55d0349c159a

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 3, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARL4A | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.383); catalogued as COSV63319175; called by muse, mutect2, varscan2
- ARMC5 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.879); catalogued as COSV51655652; called by muse, mutect2, varscan2
- C2orf16 | c.3089C>A p.S1030* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV62674578; called by muse, mutect2, varscan2
- CDH1 | c.2600A>G p.N867S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.264); catalogued as rs587782623, COSV55730131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXOSC9 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV54665486; called by muse, mutect2, varscan2
- FAM153B | c.1085C>T p.P362L (on ENST00000253490; = p.P285L on NM_001265615.1) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV53685855; called by mutect2, varscan2
- GRIN2B | c.4203C>A p.S1401R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs772027875, COSV74205359; called by muse, mutect2, varscan2
- HDX | c.116A>C p.Q39P | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52974694; called by muse, mutect2, varscan2
- LRRC4C | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53421571; called by muse, mutect2, varscan2
- MAP3K12 | c.1515-1G>A p.X505_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57232125; called by muse, mutect2, varscan2
- MYT1L | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67701872; called by muse, mutect2, varscan2
- SHANK3 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758053583, COSV53185228; called by muse, mutect2, varscan2
- TFAP2A | c.268C>G p.Q90E (on ENST00000482890; = p.Q82E on NM_001032280.3) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.759); catalogued as COSV100117264, COSV60233242; called by muse, mutect2
- XIRP2 | c.6416C>T p.P2139L (on ENST00000628543; = p.P2314L on NM_152381.6) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1559042709, COSV54690617; called by muse, mutect2, varscan2
- MAP2K4 | c.955_956del p.Q319Sfs*11 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by pindel, varscan2
- PDS5B | c.841_845del p.L281Efs*3 | Frame Shift Del (DEL) | VAF 21/123 reads (17%) | called by pindel, varscan2
- TLR8 | c.743del p.L248* (on ENST00000218032 / NM_138636.5; = p.L266* on NM_016610.4) | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ARMC5 | c.1224G>A p.Q408= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV51655642; called by muse, mutect2, varscan2
- MEFV | c.1788T>C p.H596= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1312420603, COSV54820072; called by muse, mutect2, varscan2
- WSCD2 | c.711C>T p.F237= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV54580354; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288305C>A | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs751373458; called by muse, mutect2, varscan2
